Somatic mutation profile of tumor specimen TCGA-WB-A80K-01A (aliquot TCGA-WB-A80K-01A-11D-A35I-08) from TCGA case TCGA-WB-A80K, project TCGA-PCPG (Pheochromocytoma and Paraganglioma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Pheochromocytoma, NOS; Tissue or organ of origin: Adrenal gland, NOS; Age at diagnosis: 49.4 years (18,033 days).
Specimen TCGA-WB-A80K-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 037be712-f4ac-4561-b12d-b46364bcc319.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-WB-A80K-10A (Blood Derived Normal), aliquot TCGA-WB-A80K-10A-01D-A35G-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/9c7a5791-2ada-40a4-94a6-5aef74c0d54c

The open-access MAF lists 11 somatic variants for this specimen: 8 protein-altering or splice-affecting, 2 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 8, Silent 2, 5'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- GPR50 | c.1212C>G p.H404Q | Missense Mutation (SNP) | VAF 5/71 reads (7%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.041); catalogued as COSV54443749; called by muse, mutect2
- MEGF10 | c.1322C>T p.T441I | Missense Mutation (SNP) | VAF 63/125 reads (50%) | SIFT tolerated (0.35); PolyPhen benign (0); catalogued as rs1160030961; called by muse, mutect2, varscan2
- PDE4A | c.1973C>T p.A658V (on ENST00000380702 / NM_001111307.2; = p.A419V on NM_006202.3) | Missense Mutation (SNP) | VAF 41/119 reads (34%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.956); catalogued as rs751655561; called by muse, mutect2, varscan2
- PTCRA | c.245C>T p.T82M | Missense Mutation (SNP) | VAF 14/75 reads (19%) | SIFT tolerated (0.08); PolyPhen benign (0.003); catalogued as rs773148448; called by muse, mutect2, varscan2
- ECT2 | c.819T>G p.D273E (on ENST00000392692 / NM_001349098.2; = p.D242E on NM_018098.6 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 5/41 reads (12%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.796); called by muse, mutect2, varscan2
- GCKR | c.815C>G p.T272S | Missense Mutation (SNP) | VAF 5/78 reads (6%) | SIFT tolerated (0.07); PolyPhen benign (0.084); called by muse, mutect2
- SCARB1 | c.904G>C p.V302L | Missense Mutation (SNP) | VAF 18/62 reads (29%) | SIFT deleterious (0.04); PolyPhen benign (0.102); called by muse, mutect2, varscan2
- SEMA6D | c.3136C>T p.P1046S (on ENST00000316364 / NM_153618.2; = p.P984S on NM_020858.2) | Missense Mutation (SNP) | VAF 20/216 reads (9%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.698); called by muse, mutect2
- PHB | c.474C>T p.A158= | Silent (SNP) | VAF 12/58 reads (21%) | catalogued as rs201875820, COSV100303219; called by muse, mutect2, varscan2
- TFAP4 | c.114C>G p.P38= | Silent (SNP) | VAF 5/93 reads (5%) | called by muse, mutect2
- ING1 | chr13:110714240 C>G | 5'Flank (SNP) | VAF 13/51 reads (25%) | called by muse, mutect2, varscan2
